Somatic mutation profile of tumor specimen MP2PRT-PANRWZ-TMP1-A (aliquot MP2PRT-PANRWZ-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANRWZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,876 days).
Specimen MP2PRT-PANRWZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43436b13-90b5-49b3-b787-61c1ca975b91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANRWZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANRWZ-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/830b9a86-fbbe-4038-87f6-a83c6374e511

The open-access MAF lists 22 somatic variants for this specimen: 11 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 8, 5'UTR 2, 3'Flank 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTN1A1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 187/488 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV55070576; called by muse, mutect2, varscan2
- ERBB4 | c.1399T>G p.C467G | Missense Mutation (SNP) | VAF 246/617 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53586772; called by muse, mutect2
- FAT3 | c.11824C>T p.R3942W | Missense Mutation (SNP) | VAF 209/272 reads (77%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.847); catalogued as rs190745363, COSV53110854; called by muse, mutect2, varscan2
- FN1 | c.3659C>T p.S1220F | Missense Mutation (SNP) | VAF 164/452 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.859); catalogued as COSV60546452, COSV60550057; called by muse, mutect2, varscan2
- IFT74 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66287770; called by muse, mutect2, varscan2
- LRFN5 | c.379C>T p.H127Y | Missense Mutation (SNP) | VAF 30/536 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53244329; called by muse, mutect2
- R3HDM4 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 182/431 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); catalogued as rs772340521; called by muse, mutect2, varscan2
- ZBED9 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 118/291 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV71729207; called by muse, mutect2, varscan2
- BTC | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 107/306 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC74A | c.1065_1067del p.K355del | In Frame Del (DEL) | VAF 212/520 reads (41%) | called by pindel, varscan2
- ERBB4 | c.1397T>G p.L466R | Missense Mutation (SNP) | VAF 243/614 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADCK1 | c.511C>A p.R171= | Silent (SNP) | VAF 231/562 reads (41%) | called by muse, mutect2, varscan2
- DOCK4 | c.4896G>A p.P1632= | Silent (SNP) | VAF 115/281 reads (41%) | catalogued as rs1274497749, COSV70238413; called by muse, mutect2, varscan2
- JAKMIP3 | c.441C>T p.F147= | Silent (SNP) | VAF 287/699 reads (41%) | catalogued as rs751886326, COSV53822397; called by muse, mutect2, varscan2
- LAMA4 | c.5274G>T p.L1758= (on ENST00000230538 / NM_001105206.3; = p.L1751= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 166/439 reads (38%) | called by muse, mutect2, varscan2
- RBP3 | c.1215C>T p.A405= | Silent (SNP) | VAF 242/585 reads (41%) | catalogued as rs782291267; called by muse, mutect2, varscan2
- RTL3 | c.1050G>A p.L350= | Silent (SNP) | VAF 23/721 reads (3%) | called by muse, mutect2
- RYR2 | c.9951T>A p.T3317= | Silent (SNP) | VAF 169/364 reads (46%) | called by muse, mutect2, varscan2
- ZNF184 | c.2205C>T p.F735= | Silent (SNP) | VAF 33/479 reads (7%) | catalogued as COSV99279828; called by muse, mutect2
- IGKV1D-8 | chr2:90221384 ins CCA | 3'Flank (INS) | VAF 42/64 reads (66%) | called by pindel, varscan2
- MAGEB10 | c.-1C>T | 5'UTR (SNP) | VAF 133/367 reads (36%) | catalogued as rs749983935; called by muse, mutect2, varscan2
- PRKAR2B | c.-192C>A | 5'UTR (SNP) | VAF 145/513 reads (28%) | called by muse, mutect2, varscan2
